Somatic mutation profile of tumor specimen TCGA-CN-5374-01A (aliquot TCGA-CN-5374-01A-01D-1434-08) from TCGA case TCGA-CN-5374, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 56.0 years (20,464 days).
Specimen TCGA-CN-5374-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fbf9b68-ed06-4d1f-a3c9-c48f124d4714.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5374-10A (Blood Derived Normal), aliquot TCGA-CN-5374-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d76c6e25-1f4d-4c9f-b085-25b9bfb2c02c

The open-access MAF lists 163 somatic variants for this specimen: 123 protein-altering or splice-affecting, 37 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 37, Nonsense Mutation 10, Splice Region 3, RNA 2, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAGAB | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 45/311 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV99971939; called by muse, mutect2, varscan2
- ADCY3 | c.3262G>A p.E1088K | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV99568396; called by muse, mutect2
- ALPK3 | c.2192G>A p.S731N | Missense Mutation (SNP) | VAF 29/211 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV99361094; called by muse, mutect2, varscan2
- ANO4 | c.2057C>A p.P686H (on ENST00000392977 / NM_001286615.2; = p.P651H on NM_178826.4) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54583739, COSV54602500; called by muse, mutect2, varscan2
- ARFGEF2 | c.4677G>T p.L1559F | Missense Mutation (SNP) | VAF 11/256 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64213022; called by muse, mutect2
- ARHGAP21 | c.3636A>G p.K1212= | Splice Region (SNP) | VAF 17/89 reads (19%) | catalogued as rs1470585777, COSV100256327; called by muse, mutect2, varscan2
- BAHCC1 | c.6499G>A p.E2167K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs782636371, COSV57034172; called by muse, mutect2, varscan2
- CCDC87 | c.2338G>C p.E780Q | Missense Mutation (SNP) | VAF 46/310 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as COSV100040020; called by muse, mutect2
- CCDC87 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs762152279, COSV100040021; called by muse, mutect2, varscan2
- CDH19 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 22/147 reads (15%) | catalogued as COSV100051684; called by muse, mutect2, varscan2
- CFAP91 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 42/391 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs565776294, COSV56342427, COSV99847038; called by muse, mutect2, varscan2
- CHD9 | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373596251; called by muse, mutect2, varscan2
- CLCN1 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); catalogued as COSV100578117, COSV58373701; called by muse, mutect2
- CLEC4C | c.413C>A p.S138Y | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.759); catalogued as COSV63582424; called by muse, mutect2, varscan2
- CMA1 | c.162C>G p.F54L | Missense Mutation (SNP) | VAF 63/358 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99157412, COSV99157495; called by muse, mutect2, varscan2
- COG1 | c.701G>A p.R234K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs750285470, COSV55429138, COSV55430332; called by muse, mutect2, varscan2
- CRYBG1 | c.4253G>C p.R1418T | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.438); catalogued as COSV100954517; called by muse, mutect2
- CSMD3 | c.7829G>T p.C2610F (on ENST00000297405 / NM_001363185.1; = p.C2506F on NM_052900.3) | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99827664, COSV99836455; called by muse, mutect2, varscan2
- CYLD | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.79); PolyPhen benign (0.233); catalogued as rs772008589, COSV100282479; called by muse, mutect2, varscan2
- DCHS1 | c.9740C>T p.S3247L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as rs977153762, COSV54996660; called by muse, mutect2, varscan2
- DHX33 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99834398; called by muse, mutect2, varscan2
- DLEC1 | c.1102G>T p.D368Y | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.407); catalogued as rs1452242079, COSV57299504; called by muse, mutect2, varscan2
- DLGAP2 | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs773355695, COSV101421011, COSV70099049; called by muse, mutect2, varscan2
- DST | c.5144C>G p.S1715C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV55004811; called by muse, mutect2, varscan2
- DUOX1 | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 19/176 reads (11%) | catalogued as rs756239895, COSV50993204, COSV99973418; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1138C>G p.Q380E | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.421); catalogued as rs1216879631, COSV50051381; called by muse, mutect2, varscan2
- EFHB | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV99859671; called by muse, mutect2, varscan2
- ESM1 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101195716, COSV67318511; called by muse, mutect2, varscan2
- FAM135B | c.3052G>C p.E1018Q | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV52713810; called by muse, mutect2, varscan2
- FAM98A | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 48/381 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV99479343; called by muse, mutect2, varscan2
- FANCB | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 5/107 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.421); catalogued as COSV100146581; called by muse, mutect2
- FBN3 | c.5923G>C p.E1975Q | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as rs530861137, COSV99561102; called by muse, mutect2, varscan2
- FBXO44 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV52353728; called by muse, mutect2
- FGFR4 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV99450012; called by muse, mutect2, varscan2
- FN1 | c.790G>A p.G264S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs950443871, COSV60548392; called by muse, mutect2, varscan2
- FUBP1 | c.1239G>C p.Q413H | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99628963; called by muse, mutect2, varscan2
- GATC | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV56663480, COSV56663769; called by muse, mutect2, varscan2
- GCNT2 | c.988G>A p.D330N (on ENST00000379597 / NM_001374747.1; = p.D328N on NM_001491.3) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV99399038, COSV99399348; called by muse, mutect2, varscan2
- GIMAP5 | c.588G>C p.Q196H | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100500212; called by muse, mutect2, varscan2
- GTF3C3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99826762; called by muse, mutect2
- GUCY1A1 | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99637891; called by muse, mutect2, varscan2
- H3C11 | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.041); catalogued as COSV100137938; called by muse, mutect2
- HAUS8 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV99505338; called by muse, mutect2, varscan2
- IARS1 | c.396G>A p.K132= | Splice Region (SNP) | VAF 35/234 reads (15%) | catalogued as rs1564190097, COSV100986828; called by muse, mutect2, varscan2
- IRX1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as rs1184051517, COSV57359452; called by muse, mutect2, varscan2
- ITIH4 | c.2395G>C p.E799Q | Missense Mutation (SNP) | VAF 51/367 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV99819482; called by muse, mutect2, varscan2
- JAKMIP1 | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs530379301, COSV51525585; called by muse, mutect2, varscan2
- KCTD11 | c.751G>C p.D251H (on ENST00000333751 / NM_001363642.1; = p.D212H on NM_001002914.2) | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99341727; called by muse, mutect2
- KIAA1210 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV68176300; called by muse, mutect2, varscan2
- KIF11 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.471); catalogued as rs780485814, COSV99585904; called by muse, mutect2, varscan2
- KIF13A | c.2800G>T p.V934L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.224); catalogued as COSV99436311; called by mutect2, varscan2
- KMT5B | c.2574G>C p.L858F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58564803; called by muse, mutect2, varscan2
- L3MBTL1 | c.1756G>A p.A586T (on ENST00000418998 / NM_001377303.1; = p.A496T on NM_015478.7) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.817); catalogued as rs766968999, COSV64228396; called by mutect2, varscan2
- LPAR4 | c.41C>G p.S14* | Nonsense Mutation (SNP) | VAF 29/158 reads (18%) | catalogued as COSV70912382; called by muse, mutect2, varscan2
- LRRCC1 | c.1259A>C p.D420A | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV64483007; called by muse, mutect2, varscan2
- LRRTM1 | c.356C>T p.T119M | Missense Mutation (SNP) | VAF 64/255 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV99702639; called by muse, mutect2, varscan2
- LTBP1 | c.2434G>C p.D812H (on ENST00000404816 / NM_206943.4; = p.D486H on NM_000627.4) | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1425709261, COSV100617297; called by muse, mutect2
- MANEA | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754208058, COSV100721547; called by muse, mutect2
- MAU2 | c.1586C>T p.A529V | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53234344; called by muse, mutect2, varscan2
- MEFV | c.1804C>A p.L602M | Missense Mutation (SNP) | VAF 66/466 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54825146, COSV99560661; called by muse, mutect2, varscan2
- MME | c.1839T>G p.S613R | Missense Mutation (SNP) | VAF 50/209 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100852423; called by muse, mutect2, varscan2
- MTMR14 | c.515C>A p.A172E | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99931338; called by muse, mutect2, varscan2
- MUC16 | c.11255C>T p.S3752L | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.101); catalogued as rs541416348, COSV67454655; called by muse, mutect2, varscan2
- MYH6 | c.3880G>A p.E1294K | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as COSV100676660; called by muse, mutect2
- MYO18B | c.4414C>T p.R1472W | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374116001; called by muse, mutect2
- NAA25 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | catalogued as COSV55703099, COSV55705489; called by muse, mutect2, varscan2
- NAV2 | c.3969C>A p.R1323= (on ENST00000396087 / NM_001244963.2; = p.R1300= on NM_145117.5) | Splice Region (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100217088; called by muse, mutect2, varscan2
- NCF2 | c.305G>C p.R102P | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs137854515, CM101799, COSV100838902; ClinVar: not provided; called by muse, mutect2, varscan2
- NPR3 | c.1322G>A p.R441H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1177943172, COSV54085697; called by muse, mutect2, varscan2
- NPY5R | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100642804; called by muse, mutect2, varscan2
- NRIP2 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61701293; called by muse, mutect2, varscan2
- OR4E2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs775574914, COSV100330023, COSV100330110; called by muse, mutect2, varscan2
- PC | c.1843G>A p.A615T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs773466708, COSV101211979; called by muse, mutect2, varscan2
- PDCD2L | c.823T>A p.F275I | Missense Mutation (SNP) | VAF 19/461 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV99875016; called by muse, mutect2
- PDE10A | c.2327C>T p.S776L | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV63105601; called by muse, mutect2, varscan2
- PIWIL3 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 126/819 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100177691; called by muse, mutect2, varscan2
- PKMYT1 | c.1238C>A p.P413Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99234104; called by muse, mutect2
- PLCH1 | c.2977G>A p.E993K (on ENST00000340059 / NM_001130960.2; = p.E985K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.005); catalogued as COSV100397108, COSV58185195; called by muse, mutect2
- PLSCR2 | c.605T>C p.L202P (on ENST00000497985 / NM_001199978.1; = p.L129P on NM_020359.2) | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100367720; called by muse, mutect2
- POPDC2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51743109; called by muse, mutect2
- PREX1 | c.988C>T p.R330* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | catalogued as COSV100906012; called by muse, mutect2
- PRMT5 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53545256; called by muse, mutect2, varscan2
- PRPF6 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV53878244, COSV99412127; called by muse, mutect2, varscan2
- PRPS1 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 63/383 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV100978868, COSV100978883; called by muse, mutect2, varscan2
- RMND1 | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 57/176 reads (32%) | catalogued as COSV60550193; called by muse, mutect2, varscan2
- RP1 | c.4987G>A p.E1663K | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as COSV55113067, COSV55124855; called by muse, mutect2, varscan2
- RUFY4 | c.1541C>G p.S514C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60246727, COSV60247749; called by muse, mutect2, varscan2
- SAMM50 | c.203G>C p.G68A | Missense Mutation (SNP) | VAF 22/183 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100601384; called by muse, mutect2, varscan2
- SARDH | c.1165G>C p.D389H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100898804; called by muse, mutect2, varscan2
- SCAF8 | c.1292C>G p.S431* | Nonsense Mutation (SNP) | VAF 36/260 reads (14%) | catalogued as COSV65790905; called by muse, mutect2, varscan2
- SGMS1 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV100693428; called by muse, mutect2, varscan2
- SNAPC4 | c.2878G>A p.A960T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100047327; called by muse, mutect2, varscan2
- SP4 | c.2257G>A p.E753K | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV99754581; called by muse, mutect2, varscan2
- SPATA6 | c.79G>C p.D27H | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64060363; called by muse, mutect2, varscan2
- TAB1 | c.51G>T p.W17C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99336093; called by muse, mutect2, varscan2
- TACC3 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.834); catalogued as COSV57602629; called by muse, mutect2, varscan2
- TBC1D2 | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 93/615 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.156); catalogued as rs765947069, COSV100579943; called by muse, varscan2
- TDRD6 | c.1509G>A p.W503* | Nonsense Mutation (SNP) | VAF 24/210 reads (11%) | catalogued as COSV100287544, COSV100287739; called by muse, mutect2, varscan2
- TECTA | c.1491G>C p.W497C | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.701); catalogued as COSV99880149; called by muse, mutect2
- TEKT3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs764367004, COSV100106876; called by muse, mutect2, varscan2
- TENM1 | c.7147G>A p.G2383S | Missense Mutation (SNP) | VAF 64/209 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV64428024; called by muse, mutect2, varscan2
- TENM2 | c.4959C>G p.D1653E (on ENST00000518659 / NM_001122679.2; = p.D1414E on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.047); catalogued as COSV101318885; called by muse, mutect2, varscan2
- TF | c.950C>G p.S317C | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV99395936; called by muse, mutect2
- TMEM106C | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 201/580 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV56742343; called by muse, mutect2, varscan2
- TMEM200B | c.572C>G p.P191R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV100548786; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs370520637; called by muse, mutect2, varscan2
- TOP1 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 22/160 reads (14%) | catalogued as COSV100793729; called by muse, mutect2, varscan2
- TRPM4 | c.2070C>G p.I690M | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.278); catalogued as COSV53261265, COSV99418977; called by muse, mutect2, varscan2
- TSHZ2 | c.3088G>C p.D1030H | Missense Mutation (SNP) | VAF 9/261 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100296208; called by muse, mutect2
- TYRP1 | c.1189G>T p.D397Y | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101141330; called by muse, mutect2, varscan2
- UNC13C | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.194); catalogued as COSV99518393; called by muse, mutect2, varscan2
- UTRN | c.9115A>C p.I3039L | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.137); catalogued as COSV100837860; called by muse, mutect2, varscan2
- VCL | c.3239G>C p.S1080T (on ENST00000211998 / NM_014000.3; = p.S1012T on NM_003373.4) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); catalogued as COSV99280922; called by muse, mutect2
- WDR33 | c.2430G>A p.M810I | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV100460207; called by muse, mutect2, varscan2
- ZBTB16 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as rs776974563, COSV100251608; called by muse, mutect2
- ZCWPW2 | c.526A>G p.K176E | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs754031438, COSV101074921; called by muse, mutect2, varscan2
- ZNF155 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.2); catalogued as COSV99525716; called by muse, mutect2, varscan2
- ZNF165 | c.909G>C p.W303C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV101056120, COSV66102166; called by muse, mutect2, varscan2
- ZNF430 | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 59/164 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV55108644; called by muse, mutect2, varscan2
- ZNF483 | c.1775C>T p.S592L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV58517085; called by muse, mutect2, varscan2
- ZNF761 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 51/260 reads (20%) | catalogued as rs749679096, COSV61889043; called by muse, mutect2, varscan2
- ZNF831 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs768044968, COSV64039404, COSV64039600; called by muse, mutect2
- RGPD2 | c.5161_5162dup p.S1721Rfs*7 | Frame Shift Ins (INS) | VAF 8/56 reads (14%) | called by mutect2, varscan2
- AGL | c.2979C>T p.F993= | Silent (SNP) | VAF 35/259 reads (14%) | catalogued as COSV99649375; called by muse, mutect2, varscan2
- ATRNL1 | c.690A>G p.Q230= | Silent (SNP) | VAF 6/146 reads (4%) | catalogued as rs1003390372, COSV100745857; called by muse, mutect2
- BRD3 | c.1344G>A p.S448= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs373525654; called by muse, mutect2, varscan2
- C10orf82 | c.123C>A p.T41= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV100980118; called by muse, mutect2, varscan2
- CACNG7 | c.827G>A p.*276= | Silent (SNP) | VAF 56/308 reads (18%) | catalogued as COSV55813683; called by muse, mutect2, varscan2
- CARD10 | c.2040C>T p.P680= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV99325026; called by muse, mutect2, varscan2
- CARS2 | c.489G>A p.L163= | Silent (SNP) | VAF 42/217 reads (19%) | catalogued as rs779188351, COSV57289046, COSV99959696, COSV99960110; called by muse, mutect2, varscan2
- CHST6 | c.858G>A p.A286= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs375043854; called by muse, mutect2, varscan2
- COL2A1 | c.804G>A p.P268= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs779092796, COSV61529081; called by muse, mutect2, varscan2
- GPR85 | c.198T>C p.D66= | Silent (SNP) | VAF 18/154 reads (12%) | catalogued as COSV51783048; called by muse, mutect2, varscan2
- IKZF5 | c.565C>T p.L189= | Silent (SNP) | VAF 47/349 reads (13%) | catalogued as rs1161393830, COSV100924743; called by muse, mutect2, varscan2
- IPPK | c.528G>A p.Q176= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99845672; called by muse, mutect2, varscan2
- KCNH1 | c.801C>T p.L267= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV99659656; called by muse, mutect2, varscan2
- KCNK15 | c.519C>T p.L173= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs777664497, COSV100865134; called by muse, mutect2, varscan2
- KCNK9 | c.519C>T p.I173= | Silent (SNP) | VAF 13/89 reads (15%) | catalogued as COSV57281525; called by muse, mutect2, varscan2
- KCTD19 | c.2529C>T p.I843= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV100430992; called by muse, mutect2, varscan2
- LRP1B | c.18C>G p.L6= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV101257740; called by muse, mutect2, varscan2
- MAN2A1 | c.1956C>G p.V652= | Silent (SNP) | VAF 27/223 reads (12%) | catalogued as COSV54847815, COSV54852500; called by muse, mutect2, varscan2
- MC2R | c.231G>A p.K77= | Silent (SNP) | VAF 6/130 reads (5%) | catalogued as COSV100563032; called by muse, mutect2
- MEX3B | c.828C>T p.P276= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV61663174; called by mutect2, varscan2
- MRPS9 | c.663C>T p.F221= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV99306130; called by muse, mutect2, varscan2
- MUC16 | c.20310G>A p.Q6770= | Silent (SNP) | VAF 137/352 reads (39%) | catalogued as rs776301521, COSV67454650; called by muse, mutect2, varscan2
- PCDH12 | c.954C>T p.Y318= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs148884293; called by muse, mutect2, varscan2
- PTRH2 | c.315C>G p.L105= | Silent (SNP) | VAF 11/263 reads (4%) | catalogued as COSV52252882, COSV99292412; called by muse, mutect2
- PYROXD2 | c.282G>A p.L94= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs1564810042, COSV100996012; called by muse, mutect2, varscan2
- RALGPS1 | c.1536G>A p.L512= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as COSV52218676; called by muse, mutect2, varscan2
- RYR2 | c.9531A>G p.K3177= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV100773437, COSV63672782; called by muse, mutect2, varscan2
- SLC18A3 | c.885C>T p.A295= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs1175704238, COSV60319945; called by muse, mutect2, varscan2
- SNX30 | c.1182G>A p.Q394= | Silent (SNP) | VAF 20/105 reads (19%) | catalogued as COSV65292416; called by muse, mutect2, varscan2
- SOBP | c.1026C>T p.V342= | Silent (SNP) | VAF 26/171 reads (15%) | catalogued as COSV100433208; called by muse, mutect2, varscan2
- SPECC1L | c.1401C>T p.R467= | Silent (SNP) | VAF 44/275 reads (16%) | catalogued as rs768345667, COSV100062554; called by muse, mutect2, varscan2
- TAF1C | c.1224G>A p.V408= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100499633; called by muse, mutect2, varscan2
- THBS3 | c.522G>A p.Q174= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as COSV57425614, COSV57426139; called by muse, mutect2, varscan2
- ZNF12 | c.528C>G p.L176= (on ENST00000405858 / NM_016265.4; = p.L138= on NM_006956.3) | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs775184942, COSV100703742; called by muse, mutect2
- ZNF483 | c.1680C>T p.F560= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as COSV58516273; called by muse, mutect2, varscan2
- ZNF550 | c.546C>A p.L182= | Silent (SNP) | VAF 16/406 reads (4%) | catalogued as COSV100286673; called by muse, mutect2
- ZNF780A | c.1863T>C p.V621= | Silent (SNP) | VAF 40/210 reads (19%) | catalogued as rs1360029725, COSV100575122; called by muse, mutect2, varscan2
- MIR519C | n.42C>G | RNA (SNP) | VAF 28/228 reads (12%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.3299C>G | RNA (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- SLC25A24 | c.184-6640T>C | Intron (SNP) | VAF 308/541 reads (57%) | catalogued as COSV51446588; called by muse, mutect2, varscan2
